Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9J6, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9J6-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. "LEFT RENAL MASS," PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type 1, Fuhrman nuclear grade 2 of 4.
See Key Pathological Findings.

KEY PATHOLOGICAL FINDINGS

Tumor type:	Renal cell carcinoma, papillary type 1.
Nuclear grade:	Fuhrman nuclear grade 2 of 4.
Pattern of growth:	Solid.
Tumor size:	2.0 cm.
Invasion through Renal capsule:	Not identified.
Invasion of Gerota's Fascia:	Not applicable.
Renal vein invasion:	Not applicable.
Surgical margins:	Free.
Non-neoplastic kidney:	Mild chronic inflammation and focal glomerulosclerosis.
Adrenal gland:	Not applicable.
Lymph nodes:	Not applicable.
Pathologic stage:	pT1aNXMX.

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by _____

Specimen(s) Received

A LEFT RENAL MASS

Clinical History

-year-old male with left renal mass.

Preoperative Diagnosis

Not given.

Frozen Section Diagnosis

FSA1: LEFT RENAL MASS:
Renal cell carcinoma with papillary features.
Margin negative.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr. _____ in OR _____ at _____

I, _____ M.D., have performed the intraoperative consultation and issued the above diagnosis.

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site: D Kidney NOS
C64.9
JW 4/28/14

[page 2 of 2]
Gross Description

A. The specimen is received fresh labeled "left renal mass". The specimen consists of a 2.0 x 1.8 x 1.5 cm mass surrounded by a rim of renal parenchyma. This rim ranges in size from 0.2 to 0.8 cm. The specimen is inked as follows:

Blue: Capsule around tumor
Green and black: Renal parenchymal margin

The specimen is serially sectioned to reveal a tan-yellow, homogenous and well-encapsulated mass that does not involve the renal capsule or perinephric fat. The rim of renal parenchyma seems unremarkable. The specimen is submitted as follows:

FSA1: Tumor and renal parenchymal margin submitted for frozen section diagnosis
A2-A6: Sections of remaining tumor in relation to capsule and renal parenchyma

Representative section of this tumor was submitted to the Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file 14fba30a-e0da-4721-bcd5-1e0f505ba208 (TCGA-2Z-A9J6.4EE74737-16F3-44DD-A18F-B418F17F6FAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).